Somatic mutation profile of tumor specimen 0DSR50 from CCDI case PBCIPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.6 years (2,398 days).
Specimen 0DSR50: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c83f9df4-d43f-46f0-b4e9-d182b46eed02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSR5C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56c87c32-b3bd-475b-bd99-75129986ff64

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PJA2 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 20/439 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- GCNA | c.-73T>C | 5'UTR (SNP) | VAF 10/151 reads (7%) | catalogued as rs1178419723; called by muse, mutect2
- NR4A3 | c.*72G>C | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, varscan2
- ZNF577 | c.187+77G>C | Intron (SNP) | VAF 10/62 reads (16%) | called by muse, varscan2
